Surgical pathology report (de-identified scan), TCGA case TCGA-HW-8321, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-8321-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

Left frontal intra axial primary brain tumor with enhancement malignant glioma.

Specimens Submitted:

- 1: Left frontal brain tumor
- 2: Left frontal brain tumor # 2
- 3: Enlarging region left frontal lobe brain tumor

DIAGNOSIS:

1. Frontal brain,lef
- Diffusely infiltrating glioma, see below.
2. Frontal brain# 2;biopsy:
- Diffusely infiltrating glioma with focally increased proliferative activity, see note.
3. Enlarging region frontal lobe, brain,left;biopsy:
- Diffusely infiltrating glioma with focally increased proliferative activity, see note.

Note: While this infiltrating glial neoplasm exhibits some oligodendroglial features, it is predominantly of astrocytic appearance and we think that it fundamentally represents a diffuse astrocytoma. A subset of tumor cells labels for p53. There is tumor expression of R132H mutant IDH1. The great majority of this lesion is at the WHO grade II level and manifests low MIB-1 labeling activity. We find a solitary focus in specimen 2 in which a number of mitotic figures can be identified and in which the MIB-1 labeling index rises into the 8-10% range. Given the increased proliferative activity, this would qualify as regional progression to the anaplastic/ WHO grade III level though the focus in question is quite limited in volume. Material has been forwarded for MGMT promoter methylation analysis and chromosome 1p/19q deletion testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	MIB-1 (Ki-67)	
	P53	
	IDH1-H09	
	RECUT	
	Unst_Recut	
	NEG CONT	
	IMM RECUT	
	NEG CONT	
	IMM RECUT	
	IDH1-H09	
	MIB-1 (Ki-67)	
	MIB-1 (Ki-67)	
	NEG CONT	

[page 2 of 2]
Gross Description:

1. The specimen is received fresh for immediate surgical pathology consultation labeled "left frontal brain tumor" and consist of two tan/pink fragments of soft tissue measuring in aggregate 1.5 x 1.0 x 0.8 cm. The specimen is entirely submitted for immediate surgical pathology consultation. Two touch prep slides have been prepared.

Summary of sections:

FSC - frozen section control

2). The specimen is received fresh, labeled "Left frontal lobe brain tumor # 2" and consists of a 7.5 x 6.5 x 2.5 cm aggregate of white-tan brain matter. Sectioning of the larger fragments reveals a white-tan to gray glistening cut surface. Representative sections are submitted.

Summary of sections

U--undesignated

3). The specimen is received fresh, labeled "Enhancing region left frontal lobe brain tumor" and consists of an aggregate of tan-gay brain matter measuring 2.0 x 1.0 x 0.8 cm. The specimen is entirely submitted.

Summary of sections:

U--undesignated

Summary of Sections:**Part 1: Left frontal brain tumor (fs)**

Block	Sect. Site	PCs
1	FSC	0

Part 2: Left frontal brain tumor # 2

Block	Sect. Site	PCs
5	U	10

Part 3: Enlarging region left frontal lobe brain tumor

Block	Sect. Site	PCs
2	U	7

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Left frontal brain tumor (fs): Glioma with features suggestive of anaplasia
Permanent Diagnosis: same

Source: NCI Genomic Data Commons file 39910eb7-c02e-4bb0-8b3e-2b5a69efa79d (TCGA-HW-8321.985F7F28-3F83-4CDA-BFC8-6676BBFFD7B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).